Somatic mutation profile of tumor specimen TCGA-F2-A7TX-01A (aliquot TCGA-F2-A7TX-01A-33D-A38G-08) from TCGA case TCGA-F2-A7TX, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,239 days).
Specimen TCGA-F2-A7TX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 779f7624-6c69-46e8-b4e9-2bb27de6216b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-A7TX-10B (Blood Derived Normal), aliquot TCGA-F2-A7TX-10B-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/085b24cb-412c-411c-bc20-fb211db8703b

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/363 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 99/401 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 34/184 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99522898; called by muse, mutect2, varscan2
- ARID1A | c.3715+1G>A p.X1239_splice | Splice Site (SNP) | VAF 27/196 reads (14%) | catalogued as COSV100250206, COSV61382095; called by muse, mutect2, varscan2
- CCDC8 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 80/571 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs892022177, COSV56772244; called by muse, mutect2, varscan2
- CMIP | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV101607047; called by muse, mutect2, varscan2
- CYB5R1 | c.62T>A p.L21H | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV100924871; called by muse, mutect2
- DDX59 | c.1660A>G p.K554E | Missense Mutation (SNP) | VAF 34/425 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100494756, COSV100494791; called by muse, mutect2
- DLL4 | c.1004A>T p.N335I | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99990045; called by muse, mutect2
- DNAH5 | c.7292C>T p.S2431F | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV99454891, COSV99455594; called by muse, mutect2
- FAM135B | c.57T>A p.N19K | Missense Mutation (SNP) | VAF 75/455 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV50526945, COSV99358455; called by muse, mutect2, varscan2
- HOXB3 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57488220; called by muse, mutect2
- IQCD | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 104/723 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100232539; called by muse, mutect2, varscan2
- KCNK3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM136952, COSV100257283; called by muse, mutect2, varscan2
- KLHDC8A | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs1335565294, COSV100903887; called by muse, mutect2
- LTBP2 | c.5254C>T p.R1752W | Missense Mutation (SNP) | VAF 75/481 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs756787943, COSV56214591; called by muse, mutect2, varscan2
- MAPT | c.728G>A p.R243H (on ENST00000262410 / NM_001377265.1; = p.R168H on NM_016835.4) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1356540236, COSV99291561; called by muse, mutect2, varscan2
- MTNR1B | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 49/313 reads (16%) | catalogued as rs748364564, COSV99925426; called by muse, mutect2, varscan2
- MYO9B | c.4804G>A p.G1602S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV101262031; called by muse, varscan2
- NPAT | c.2902G>A p.V968I | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV99586450; called by muse, mutect2
- NUDT6 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1185671692, COSV99916676; called by muse, mutect2, varscan2
- OR13C2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73377674; called by muse, mutect2
- PCDHGA2 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 89/528 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV54032525, COSV99549413; called by muse, mutect2, varscan2
- SGIP1 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99393321; called by muse, mutect2
- SLC1A3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 138/886 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1260597532, COSV99468505; called by muse, mutect2, varscan2
- TAF4 | c.1727T>C p.V576A | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV99435283; called by muse, mutect2
- TIE1 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs895434484, COSV100992253; called by muse, mutect2
- TMEM132D | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs368850505; called by muse, mutect2, varscan2
- TXK | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 87/559 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99972990; called by muse, mutect2, varscan2
- UBR2 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 128/470 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs754681331, COSV65749237; called by muse, mutect2, varscan2
- UNC13C | c.1614G>C p.Q538H | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99521797, COSV99524339; called by muse, mutect2, varscan2
- VWA8 | c.3496C>T p.H1166Y | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV101023106; called by muse, mutect2, varscan2
- AC100868.1 | c.1285del p.A429Lfs*4 | Frame Shift Del (DEL) | VAF 95/500 reads (19%) | called by mutect2, pindel, varscan2
- KMT2D | c.7471dup p.A2491Gfs*15 | Frame Shift Ins (INS) | VAF 43/231 reads (19%) | called by mutect2, pindel, varscan2
- KMT2E | c.2404dup p.R802Kfs*8 | Frame Shift Ins (INS) | VAF 49/384 reads (13%) | called by mutect2, pindel, varscan2
- CYP2W1 | c.939C>T p.G313= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100417355; called by muse, mutect2
- FBXO44 | c.192C>T p.P64= | Silent (SNP) | VAF 57/382 reads (15%) | catalogued as rs772816291, COSV99279151; called by muse, mutect2, varscan2
- FLG2 | c.6162C>T p.A2054= | Silent (SNP) | VAF 176/2060 reads (9%) | catalogued as rs1557894458, COSV101165631, COSV101166321; called by muse, mutect2
- KMT2D | c.7866C>T p.D2622= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as rs773435188, COSV99986662; called by muse, mutect2
- MANEAL | c.279C>A p.P93= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100203996; called by muse, mutect2
- MTNR1B | c.1065G>A p.V355= | Silent (SNP) | VAF 48/318 reads (15%) | catalogued as COSV99925425; called by muse, mutect2, varscan2
- RIMBP2 | c.1713C>T p.G571= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1294139503, COSV55470318; called by muse, mutect2, varscan2
- SSTR1 | c.351C>T p.S117= | Silent (SNP) | VAF 56/792 reads (7%) | catalogued as rs1478362711, COSV99943245; called by muse, mutect2
- TRIM68 | c.531G>T p.V177= | Silent (SNP) | VAF 11/267 reads (4%) | called by muse, mutect2
- XYLT1 | c.1995G>A p.T665= | Silent (SNP) | VAF 70/327 reads (21%) | catalogued as rs779046536, COSV54486273, COSV99763739; called by muse, mutect2
- DHRS4L1 | n.79G>A | RNA (SNP) | VAF 16/119 reads (13%) | catalogued as rs556461153; called by muse, mutect2, varscan2
- RFX7 | c.-218A>G | 5'UTR (SNP) | VAF 8/73 reads (11%) | catalogued as rs1281942586, COSV100429563; called by muse, mutect2
